Somatic mutation profile of tumor specimen MMRF_1739_1_BM_CD138pos (aliquot MMRF_1739_1_BM_CD138pos_T1_KBS5U_L04794) from MMRF case MMRF_1739, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 45.4 years (16,576 days).
Specimen MMRF_1739_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d42fb04d-050a-4ca1-95d6-92761cb983e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1739_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1739_1_PB_Whole_C3_KBS5U_L04806; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a06c1f40-dcb6-4c81-8701-c46aa6574802

The open-access MAF lists 125 somatic variants for this specimen: 53 protein-altering or splice-affecting, 13 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, 3'UTR 32, Intron 17, Silent 13, RNA 4, 5'UTR 4, Nonsense Mutation 3, Frame Shift Del 3, Splice Site 2, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRIN2B | c.1619G>A p.R540H | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs672601378, CM141567, COSV74204705, COSV74205512; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 61/132 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AP1G1 | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 21/224 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100250944; called by muse, mutect2
- ATAD3A | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as rs551101347; called by muse, mutect2, varscan2
- BAHCC1 | c.5809G>A p.D1937N | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782505832; called by muse, mutect2, varscan2
- CASP5 | c.476C>G p.S159C | Missense Mutation (SNP) | VAF 63/206 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.807); catalogued as rs894001761, COSV99507867; called by muse, mutect2, varscan2
- CEP152 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 27/158 reads (17%) | catalogued as rs939206074; called by muse, mutect2, varscan2
- DENND2C | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.881); catalogued as COSV67919959; called by muse, mutect2, varscan2
- ERN2 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.79); PolyPhen benign (0.021); catalogued as rs199789139; called by muse, mutect2, varscan2
- HPR | c.637A>G p.N213D | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375115348; called by muse, mutect2, varscan2
- HS6ST2 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as COSV63712623; called by muse, mutect2, varscan2
- IGLV4-69 | c.150C>G p.S50R | Missense Mutation (SNP) | VAF 53/221 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as rs377689317; called by muse, mutect2, varscan2
- MCAM | c.380G>T p.R127L | Missense Mutation (SNP) | VAF 54/217 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as rs147390678; called by muse, mutect2, varscan2
- NCOR1 | c.1083-2A>G p.X361_splice | Splice Site (SNP) | VAF 33/92 reads (36%) | catalogued as COSV51959350; called by muse, mutect2, varscan2
- NMUR2 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.567); catalogued as rs750095849, COSV99676648, COSV99676784; called by mutect2, varscan2
- OR2T10 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs538661920; called by muse, mutect2, varscan2
- PODN | c.1283G>A p.R428H (on ENST00000395871; = p.R380H on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs1417440191, COSV57013551, COSV57014799; called by muse, mutect2, varscan2
- PPP2R5B | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs959789177; called by muse, mutect2, varscan2
- PROM2 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768063789, COSV58299784; called by muse, mutect2, varscan2
- PTCHD3 | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 18/174 reads (10%) | catalogued as COSV71257109; called by muse, mutect2, varscan2
- RANBP6 | c.2362A>G p.M788V | Missense Mutation (SNP) | VAF 158/257 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as rs1463261627; called by muse, mutect2, varscan2
- RPL10 | c.208A>C p.I70L | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV50010499; called by muse, mutect2, varscan2
- TACC2 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs202197379; called by muse, mutect2, varscan2
- VWDE | c.2100del p.K700Nfs*3 | Frame Shift Del (DEL) | VAF 32/114 reads (28%) | catalogued as rs781003137; called by mutect2, varscan2
- WDR97 | c.1652G>A p.G551D | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs1417165450; called by muse, mutect2, varscan2
- ANK3 | c.11884A>G p.T3962A | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- BEST2 | c.1429C>A p.P477T | Missense Mutation (SNP) | VAF 53/232 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC160 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CFAP53 | c.1057G>T p.E353* | Nonsense Mutation (SNP) | VAF 108/243 reads (44%) | called by muse, mutect2, varscan2
- DMXL2 | c.6680_6683del p.N2227Ifs*13 | Frame Shift Del (DEL) | VAF 44/206 reads (21%) | called by mutect2, pindel, varscan2
- DNAJC10 | c.1785G>A p.M595I | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- DSCAML1 | c.5042T>G p.L1681R (on ENST00000321322; = p.L1621R on NM_020693.4) | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBXO28 | c.587T>G p.V196G | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FGF13 | c.38A>G p.D13G | Missense Mutation (SNP) | VAF 55/88 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- FGF14 | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- FMN2 | c.3894G>A p.W1298* | Nonsense Mutation (SNP) | VAF 12/238 reads (5%) | called by muse, mutect2
- GLCE | c.454T>C p.F152L | Missense Mutation (SNP) | VAF 28/422 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); called by muse, mutect2
- GLG1 | c.860T>C p.V287A | Missense Mutation (SNP) | VAF 108/198 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- IGHV1-69D | c.257G>C p.R86T | Missense Mutation (SNP) | VAF 54/67 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, varscan2
- IGHV2-70D | c.291_297delinsGCAAGTA p.N97K | Missense Mutation (ONP) | VAF 3/36 reads (8%) | called by muse*, pindel
- IGHV2-70D | c.143T>G p.L48R | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, varscan2
- LRRC7 | c.1090A>G p.T364A (on ENST00000651989 / NM_001370785.2; = p.T331A on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PGAP1 | c.1684G>A p.V562M | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- PLAA | c.94G>A p.G32R | Missense Mutation (SNP) | VAF 60/295 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PWP1 | c.590A>C p.D197A | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RASGRP4 | c.1889A>G p.E630G | Missense Mutation (SNP) | VAF 122/167 reads (73%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ROCK2 | c.3106A>T p.N1036Y | Missense Mutation (SNP) | VAF 82/176 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- SH3BP5 | c.1362T>G p.I454M | Missense Mutation (SNP) | VAF 38/444 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.177); called by muse, mutect2
- TAF1 | c.2336C>T p.A779V (on ENST00000373790 / NM_138923.4; = p.A800V on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TENT5C | c.-27-14_1del | Splice Site (DEL) | VAF 47/394 reads (12%) | called by mutect2, pindel
- THSD4 | c.2974_2975del p.V992Lfs*35 | Frame Shift Del (DEL) | VAF 38/178 reads (21%) | called by pindel, varscan2
- TMC3 | c.2669T>C p.I890T | Missense Mutation (SNP) | VAF 43/245 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TRIM42 | c.861G>T p.E287D | Missense Mutation (SNP) | VAF 18/340 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.76); called by muse, mutect2
- ADGRV1 | c.15174T>A p.V5058= | Silent (SNP) | VAF 14/370 reads (4%) | called by muse, mutect2
- B4GALNT4 | c.2823C>T p.P941= | Silent (SNP) | VAF 16/236 reads (7%) | catalogued as COSV57323173; called by muse, mutect2
- CDH26 | c.30G>A p.S10= | Silent (SNP) | VAF 56/125 reads (45%) | catalogued as rs928943004, COSV54846503; called by muse, mutect2, varscan2
- DNAH14 | c.8010C>T p.D2670= (on ENST00000445597; = p.D3473= on NM_001367479.1) | Silent (SNP) | VAF 47/111 reads (42%) | catalogued as rs767369208; called by muse, mutect2, varscan2
- DOHH | c.441G>T p.V147= | Silent (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2, varscan2
- HMCN2 | c.1158C>T p.G386= | Silent (SNP) | VAF 76/204 reads (37%) | catalogued as rs547987947; called by muse, mutect2, varscan2
- HS3ST4 | c.411C>T p.D137= | Silent (SNP) | VAF 13/21 reads (62%) | catalogued as rs1263012153, COSV100501909; called by muse, mutect2, varscan2
- IGHV1-69D | c.349A>C p.R117= | Silent (SNP) | VAF 21/34 reads (62%) | called by muse, varscan2
- ILK | c.664C>T p.L222= | Silent (SNP) | VAF 10/220 reads (5%) | called by muse, mutect2
- MAGEL2 | c.2025G>A p.A675= | Silent (SNP) | VAF 44/288 reads (15%) | catalogued as rs1180033347; called by muse, mutect2, varscan2
- TEKT4 | c.69C>A p.A23= | Silent (SNP) | VAF 22/56 reads (39%) | called by muse, mutect2, varscan2
- TRIM71 | c.1392C>T p.P464= | Silent (SNP) | VAF 92/378 reads (24%) | catalogued as rs768719110, COSV67470235; called by muse, mutect2, varscan2
- ZNF644 | c.627G>T p.G209= | Silent (SNP) | VAF 85/227 reads (37%) | called by muse, mutect2, varscan2
- AC235097.1 | n.476A>T | RNA (SNP) | VAF 21/44 reads (48%) | called by muse, mutect2, varscan2
- AFF2 | c.*1171A>C | 3'UTR (SNP) | VAF 34/83 reads (41%) | called by muse, mutect2, varscan2
- AL390066.1 | n.454G>A | RNA (SNP) | VAF 13/102 reads (13%) | called by muse, mutect2, varscan2
- ANP32A | c.*861C>T | 3'UTR (SNP) | VAF 20/100 reads (20%) | called by muse, mutect2, varscan2
- APBB2 | c.*1392C>T | 3'UTR (SNP) | VAF 15/108 reads (14%) | catalogued as rs981567003; called by muse, mutect2, varscan2
- ARPP21 | c.261+1708C>T | Intron (SNP) | VAF 27/106 reads (25%) | catalogued as rs1467008920; called by muse, mutect2, varscan2
- BCL7A | chr12:122021207 T>G | 5'Flank (SNP) | VAF 49/96 reads (51%) | called by muse, mutect2, varscan2
- BMP6 | c.*709G>A | 3'UTR (SNP) | VAF 40/83 reads (48%) | catalogued as rs1181534453; called by muse, mutect2, varscan2
- C12orf76 | n.418C>A | RNA (SNP) | VAF 33/64 reads (52%) | called by muse, mutect2, varscan2
- CCDC50 | c.*2581_*2582del | 3'UTR (DEL) | VAF 62/196 reads (32%) | catalogued as rs957973818; called by mutect2, pindel, varscan2
- CNNM2 | c.*12294T>G | 3'UTR (SNP) | VAF 42/76 reads (55%) | called by muse, mutect2, varscan2
- CNTLN | c.*703C>T | 3'UTR (SNP) | VAF 22/224 reads (10%) | called by muse, mutect2
- COMMD2 | c.145+14G>C | Intron (SNP) | VAF 30/96 reads (31%) | called by muse, mutect2
- CTNND1 | c.*2584G>A | 3'UTR (SNP) | VAF 39/129 reads (30%) | called by muse, mutect2, varscan2
- CTNS | c.140+20G>A | Intron (SNP) | VAF 31/49 reads (63%) | catalogued as rs775973977; called by muse, mutect2, varscan2
- DIAPH2 | c.*5302A>C | 3'UTR (SNP) | VAF 66/139 reads (47%) | called by muse, mutect2, varscan2
- DNAH5 | c.2259+20del | Intron (DEL) | VAF 31/145 reads (21%) | catalogued as rs374448685, COSV54203709; called by mutect2, pindel, varscan2
- EIF2S1 | c.*1242G>A | 3'UTR (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2, varscan2
- ERVK13-1 | n.221G>C | RNA (SNP) | VAF 14/23 reads (61%) | called by muse, mutect2, varscan2
- FOSL2 | c.*2286T>A | 3'UTR (SNP) | VAF 27/58 reads (47%) | called by muse, mutect2, varscan2
- GABPB1 | c.-1+842T>C | Intron (SNP) | VAF 19/40 reads (48%) | called by muse, varscan2
- GIGYF1 | c.-728A>G | 5'UTR (SNP) | VAF 28/112 reads (25%) | called by muse, mutect2, varscan2
- GRK7 | c.*1039G>T | 3'UTR (SNP) | VAF 14/48 reads (29%) | catalogued as rs1250066621; called by muse, mutect2, varscan2
- IGFN1 | c.*498G>A | 3'UTR (SNP) | VAF 33/64 reads (52%) | catalogued as rs958188008; called by muse, mutect2, varscan2
- IGHM | c.*38_*40dup | 3'UTR (INS) | VAF 52/60 reads (87%) | called by mutect2, pindel, varscan2
- IL16 | c.3319-47A>G | Intron (SNP) | VAF 62/124 reads (50%) | called by muse, varscan2
- IL16 | c.3319-26T>G | Intron (SNP) | VAF 72/151 reads (48%) | called by muse, varscan2
- IQCA1 | c.*170G>A | 3'UTR (SNP) | VAF 36/70 reads (51%) | catalogued as rs1470911130, COSV99608672; called by muse, mutect2
- ISY1-RAB43 | c.*616G>A | 3'UTR (SNP) | VAF 17/53 reads (32%) | catalogued as rs878861665; called by mutect2, varscan2
- KLF15 | c.*28C>T | 3'UTR (SNP) | VAF 29/88 reads (33%) | called by muse, mutect2, varscan2
- LCA5 | c.*1485A>G | 3'UTR (SNP) | VAF 43/111 reads (39%) | called by muse, mutect2, varscan2
- LINC01551 | n.1254+18646G>A | Intron (SNP) | VAF 44/289 reads (15%) | called by muse, mutect2, varscan2
- LRCOL1 | c.231+10G>A | Intron (SNP) | VAF 47/100 reads (47%) | catalogued as rs926171953; called by muse, mutect2, varscan2
- LUZP2 | c.*1788G>A | 3'UTR (SNP) | VAF 30/141 reads (21%) | called by muse, mutect2, varscan2
- LYPD6B | c.6-724G>A | Intron (SNP) | VAF 55/128 reads (43%) | catalogued as rs192982340; called by muse, mutect2, varscan2
- MALT1 | c.-127C>G | 5'UTR (SNP) | VAF 31/69 reads (45%) | called by muse, mutect2, varscan2
- MARF1 | c.*1865A>G | 3'UTR (SNP) | VAF 22/55 reads (40%) | catalogued as rs191416157; called by muse, mutect2, varscan2
- MZT1 | c.*1931C>T | 3'UTR (SNP) | VAF 16/112 reads (14%) | called by muse, mutect2, varscan2
- NAF1 | c.-162T>C | 5'UTR (SNP) | VAF 14/41 reads (34%) | called by muse, mutect2, varscan2
- NF2 | c.*2014_*2015del | 3'UTR (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel
- NRXN1 | c.832+4792G>A | Intron (SNP) | VAF 32/63 reads (51%) | catalogued as rs1376952639; called by muse, mutect2, varscan2
- ODF4 | c.*52C>T | 3'UTR (SNP) | VAF 19/51 reads (37%) | called by muse, mutect2, varscan2
- PDLIM5 | c.*406T>C | 3'UTR (SNP) | VAF 14/31 reads (45%) | called by muse, mutect2, varscan2
- PLA2G6 | c.1349-25G>A | Intron (SNP) | VAF 23/52 reads (44%) | called by muse, mutect2, varscan2
- PLAG1 | c.*3481A>T | 3'UTR (SNP) | VAF 28/56 reads (50%) | called by muse, mutect2, varscan2
- PLCXD1 | c.*2904C>T | 3'UTR (SNP) | VAF 35/151 reads (23%) | catalogued as rs988854829; called by muse, varscan2
- POLR1F | c.-18G>A | 5'UTR (SNP) | VAF 37/121 reads (31%) | called by muse, mutect2
- ROBO1 | c.*531T>G | 3'UTR (SNP) | VAF 53/152 reads (35%) | called by muse, mutect2, varscan2
- SH3GLB2 | chr9:129007704 C>T | 3'Flank (SNP) | VAF 65/103 reads (63%) | catalogued as rs796174840; called by muse, mutect2, varscan2
- SNX30 | c.*5769C>T | 3'UTR (SNP) | VAF 11/144 reads (8%) | called by muse, mutect2
- SOCS1 | c.-50-103del | Intron (DEL) | VAF 7/8 reads (88%) | catalogued as rs1164794299; called by mutect2, varscan2
- ST3GAL5 | c.319-94C>A | Intron (SNP) | VAF 78/149 reads (52%) | called by muse, mutect2, varscan2
- SYTL4 | c.1288-163A>C | Intron (SNP) | VAF 16/36 reads (44%) | called by muse, mutect2, varscan2
- TACC2 | c.8349-69C>T | Intron (SNP) | VAF 28/66 reads (42%) | called by muse, mutect2, varscan2
- TTC39B | c.*334T>C | 3'UTR (SNP) | VAF 10/151 reads (7%) | called by muse, mutect2
- ZADH2 | c.*370C>T | 3'UTR (SNP) | VAF 30/57 reads (53%) | catalogued as rs909298672; called by muse, mutect2, varscan2
- ZDHHC18 | c.*521del | 3'UTR (DEL) | VAF 25/103 reads (24%) | catalogued as rs1220279815; called by mutect2, pindel, varscan2
- ZFP30 | c.*1259A>T | 3'UTR (SNP) | VAF 51/189 reads (27%) | called by muse, mutect2, varscan2
- ZPR1 | c.334-94G>C | Intron (SNP) | VAF 27/73 reads (37%) | called by muse, mutect2, varscan2
